Somatic mutation profile of tumor specimen TCGA-AA-3514-01A (aliquot TCGA-AA-3514-01A-02D-1953-10) from TCGA case TCGA-AA-3514, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 81.4 years (29,738 days).
Specimen TCGA-AA-3514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c1f0a21-e738-4ec7-890d-dea8ccf831fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3514-10A (Blood Derived Normal), aliquot TCGA-AA-3514-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33fea38c-cde6-4499-b7b2-6a15fcce15a0

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.5479C>T p.R1827C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs535616947, COSV65967143; called by muse, varscan2
- BSX | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 150/424 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58006118; called by muse, varscan2
- CDC25B | c.928G>A p.V310I (on ENST00000245960 / NM_021873.3; = p.V296I on NM_004358.4) | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs547724975, COSV55654269; called by muse, mutect2, varscan2
- CHST8 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1448667265, COSV52856014; called by muse, mutect2, varscan2
- DCAF12L1 | c.1279T>A p.F427I | Missense Mutation (SNP) | VAF 140/324 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV64423002; called by muse, varscan2
- DSCAM | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 164/398 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs762944210, COSV68024878; called by muse, mutect2, varscan2
- FAT4 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV101272512, COSV67894617; called by muse, mutect2, varscan2
- FBN3 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1317035484, COSV99561180, COSV99561297; called by muse, mutect2, varscan2
- FLT4 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV99987701; called by muse, varscan2
- JMJD7-PLA2G4B | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs149781451, COSV59824127; called by muse, mutect2, varscan2
- KIFC2 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV100023730, COSV100023880; called by muse, mutect2, varscan2
- LZTS2 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); catalogued as rs778752972, COSV99058735; called by muse, varscan2
- MXRA5 | c.6076G>A p.V2026M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs375991615, COSV54237684; called by muse, varscan2
- MYOM3 | c.3622G>A p.A1208T | Missense Mutation (SNP) | VAF 166/401 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs757405797, COSV58392567; called by muse, mutect2, varscan2
- PCDHA8 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 97/258 reads (38%) | catalogued as rs782317830, COSV100970840; called by muse, mutect2, varscan2
- PTPRT | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs776607737, COSV61991316, COSV62011665; called by muse, mutect2, varscan2
- ROBO2 | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.818); catalogued as rs1480209531, COSV59895971; called by muse, mutect2, varscan2
- RP1L1 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs748858444, COSV101223393; called by muse, mutect2, varscan2
- RPLP0 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV56116903; called by muse, mutect2, varscan2
- SLITRK6 | c.2351C>A p.P784H | Missense Mutation (SNP) | VAF 210/590 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV101233258; called by muse, mutect2, varscan2
- SOX9 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 121/136 reads (89%) | catalogued as COSV55423157, COSV55430562; called by muse, mutect2, varscan2
- TMEM132B | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.09); catalogued as rs919773875, COSV54762508; called by muse, mutect2, varscan2
- TMEM26 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs774929107, COSV101051709; called by muse, mutect2, varscan2
- TMPRSS2 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs757634613, COSV100151900, COSV59826416; called by muse, mutect2, varscan2
- USF3 | c.4413_4414del p.Q1472Afs*36 | Frame Shift Del (DEL) | VAF 77/192 reads (40%) | catalogued as COSV57070847; called by mutect2, varscan2*
- ZNF594 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 204/437 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV68386292; called by muse, mutect2, varscan2
- AC008397.2 | c.21C>T p.G7= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1225136003, COSV100828331; called by muse, mutect2, varscan2
- DEPDC5 | c.2646G>A p.T882= (on ENST00000400246; = p.T951= on NM_014662.5) | Silent (SNP) | VAF 169/412 reads (41%) | catalogued as rs767693306, COSV99835802; ClinVar: likely benign; called by muse, mutect2, varscan2
- ESX1 | c.129C>T p.D43= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101006479; called by muse, mutect2, varscan2
- MUTYH | c.1029G>A p.S343= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as rs372673338, CS077658; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- NLGN2 | c.981G>A p.E327= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs1333377860, COSV100259510; called by muse, mutect2
- PCDH19 | c.1638C>T p.N546= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV99719884; called by muse, mutect2, varscan2
